Gene-level copy-number profile of tumor specimen TCGA-XU-A930-01A from TCGA case TCGA-XU-A930, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B3, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 43.2 years (15,777 days).
Specimen TCGA-XU-A930-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THYM.ae6a5837-df82-47fd-876a-f5b3db8652d3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XU-A930-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/df93f33b-da5a-4ef3-96e8-4dad14106205

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8; copy number 2: 25,065; copy number 3: 23,215; copy number 4: 6,275; copy number 5: 3,301; copy number 6: 780; copy number 7: 1,137; copy number 8: 34.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XU-A930-01A-11D-A422-01): tumor purity 0.64, ploidy 4.76, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,252 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:117,953,590–121,580,524, 83 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:157,573,747–248,919,946, 1,951 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr7:70,972–21,514,822, 340 genes, copy number 5 (broad region; genes not listed).
- chr7:113,876,777–159,233,377, 930 genes, copy number 5 (broad region; genes not listed).
- chr9:14,475–28,888,955, 380 genes, copy number 5 (broad region; genes not listed).
- chr9:60,914,407–138,203,325, 1,541 genes, copy number 5 (broad region; genes not listed).
- chr19:27,638,483–28,792,871, 27 genes, copy number 5: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1.

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
